Somatic mutation profile of tumor specimen TCGA-EL-A3ZN-01A (aliquot TCGA-EL-A3ZN-01A-11D-A23M-08) from TCGA case TCGA-EL-A3ZN, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 28.1 years (10,266 days).
Specimen TCGA-EL-A3ZN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d7ec313-399a-43b9-9918-3a5763d2ac61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3ZN-11A (Solid Tissue Normal), aliquot TCGA-EL-A3ZN-11A-11D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3f1d07d-cff4-4c94-9f50-b88095052165

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IQCN | c.2676C>T p.A892= | Silent (SNP) | VAF 52/192 reads (27%) | catalogued as COSV62748568; called by muse, varscan2
- PGR | c.2298A>G p.R766= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV54808726; called by muse, mutect2
